Somatic mutation profile of tumor specimen TARGET-10-PARJBB-09A (aliquot TARGET-10-PARJBB-09A-01D) from TARGET case TARGET-10-PARJBB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (814 days).
Specimen TARGET-10-PARJBB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd050cd8-768e-4e9c-a26f-eb4b13534eb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJBB-10A (Blood Derived Normal), aliquot TARGET-10-PARJBB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d50e468-74fe-4bc7-93a1-bfa35069ab9b

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Splice Region 2, RNA 1, 3'UTR 1, Silent 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1H | c.2454C>T p.P818= | Splice Region (SNP) | VAF 22/48 reads (46%) | catalogued as rs545917540; called by mutect2, varscan2
- CAPN1 | c.267G>A p.T89= | Splice Region (SNP) | VAF 15/38 reads (39%) | catalogued as rs775574707, COSV54200437; called by muse, mutect2, varscan2
- GABRA3 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100942437, COSV64805328; called by muse, mutect2
- H3-3A | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV64732596; called by muse, mutect2, varscan2
- PCLO | c.2743G>T p.A915S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs574502381, COSV61664149; called by muse, mutect2, varscan2
- TP53 | c.847_848insTAGCGC p.R282_R283insLA | In Frame Ins (INS) | VAF 23/34 reads (68%) | catalogued as COSV53297573, COSV99037230; called by mutect2, pindel
- BMP8B | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2
- FMO3 | c.1543C>A p.L515M | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- RASA3 | c.1257C>T p.D419= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs139392233; called by muse, mutect2, varscan2
- AC074085.2 | n.42C>A | RNA (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- AP1G2 | c.1993+122_1993+123insACGTGGAGGCG | Intron (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel
- MDH1 | c.4-1060G>T | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2
- SFXN2 | c.*45C>G | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- TM7SF2 | c.1097-112G>A | Intron (SNP) | VAF 30/71 reads (42%) | catalogued as rs774923650; called by muse, mutect2, varscan2
